CCDI case PBCUHP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/08a65ffa-5a99-4abe-800f-6d59d9a03517

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0DZODW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZOFC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZOFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
